Somatic mutation profile of tumor specimen TCGA-22-1012-01A (aliquot TCGA-22-1012-01A-01D-1521-08) from TCGA case TCGA-22-1012, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 80.1 years (29,273 days).
Specimen TCGA-22-1012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a7dcc08-1eb9-4ab6-b2e2-171068021b66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1012-11A (Solid Tissue Normal), aliquot TCGA-22-1012-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01ee2e4f-9d48-4964-8f30-ff3a2d7e92f5

The open-access MAF lists 285 somatic variants for this specimen: 209 protein-altering or splice-affecting, 61 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 61, Nonsense Mutation 15, Intron 10, Splice Site 9, Frame Shift Del 9, RNA 4, Splice Region 2, Frame Shift Ins 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 32/176 reads (18%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- A1CF | c.1306C>T p.P436S (on ENST00000373993 / NM_138932.2; = p.P428S on NM_014576.4) | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV50957440, COSV50964844; called by muse, mutect2, varscan2
- AAAS | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM055898, CM065946, COSV52932932; called by muse, mutect2, varscan2
- AASS | c.2522G>A p.S841N | Missense Mutation (SNP) | VAF 229/844 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV62789962; called by muse, varscan2
- ABCA13 | c.9313C>A p.H3105N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV101446961; called by muse, mutect2, varscan2
- ABCC3 | c.1536G>T p.K512N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as COSV53321473; called by muse, mutect2, varscan2
- ABCC4 | c.3316A>G p.T1106A | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs776055053, COSV65312543; called by muse, mutect2, varscan2
- ABCF3 | c.1268A>G p.Q423R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV53052526; called by muse, mutect2, varscan2
- ACE | c.1488-2A>G p.X496_splice | Splice Site (SNP) | VAF 39/200 reads (20%) | catalogued as COSV52006673; called by muse, mutect2, varscan2
- ACSBG1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs935476084, COSV51905886; called by muse, mutect2, varscan2
- ADAMTS12 | c.4732C>A p.H1578N | Missense Mutation (SNP) | VAF 64/684 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV61262733; called by muse, mutect2
- ADGRF3 | c.1254del p.I419Sfs*42 (on ENST00000311519 / NM_001145168.1; = p.I220Sfs*42 on NM_153835.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as COSV100275239; called by mutect2, pindel, varscan2
- ADGRL4 | c.397-2A>C p.X133_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | catalogued as COSV66061579; called by muse, mutect2, varscan2
- ADRA1B | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60701689; called by muse, mutect2, varscan2
- AKAP6 | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.198); catalogued as rs1437896092, COSV55213495; called by muse, mutect2, varscan2
- ANKFN1 | c.2233G>T p.G745W | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100593498; called by muse, mutect2
- ANKRD26 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65793548; called by muse, mutect2, varscan2
- ANKRD46 | c.636+1G>A p.X212_splice (on ENST00000520552 / NM_001270379.2; = p.V213M on NM_198401.4) | Splice Site (SNP) | VAF 16/120 reads (13%) | catalogued as COSV59514390; called by muse, mutect2, varscan2
- ARFGEF2 | c.4375G>A p.G1459R | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64212230; called by muse, mutect2
- ARFGEF2 | c.4376G>T p.G1459V | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV64212232; called by muse, mutect2
- ARID4A | c.1391T>G p.L464* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV62163649; called by muse, mutect2, varscan2
- AVL9 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333957429, COSV59465594; called by muse, mutect2, varscan2
- BCAR1 | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751262673, COSV50782805; called by muse, mutect2, varscan2
- C2orf78 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV68517507; called by muse, mutect2, varscan2
- C5orf22 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57598408; called by muse, mutect2
- C6orf58 | c.227C>A p.A76E | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV61666509; called by muse, mutect2
- CA6 | c.532A>G p.S178G | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV66262146; called by muse, mutect2, varscan2
- CAPN15 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as rs374879724; called by muse, mutect2, varscan2
- CCDC27 | c.1658T>C p.L553P | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV53900122; called by muse, mutect2, varscan2
- CD1D | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV63808985; called by muse, mutect2, varscan2
- CDH10 | c.231+1G>T p.X77_splice | Splice Site (SNP) | VAF 136/274 reads (50%) | catalogued as COSV52580404; called by muse, varscan2
- CDX2 | c.542-2A>G p.X181_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as rs757964058, COSV66829472; called by mutect2, varscan2
- CEP135 | c.2797C>G p.Q933E | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.438); catalogued as COSV57259960, COSV57260710; called by muse, mutect2
- CFAP47 | c.4776G>T p.K1592N | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV57973774, COSV57976978; called by muse, mutect2, varscan2
- CHIT1 | c.749G>A p.W250* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV55146846; called by muse, mutect2, varscan2
- CHRM2 | c.759T>A p.D253E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV57771971; called by muse, mutect2, varscan2
- CHST1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV57323554; called by muse, mutect2, varscan2
- CLCN3 | c.1927G>T p.D643Y | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61627038; called by muse, mutect2, varscan2
- CLTCL1 | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54230393; called by muse, mutect2, varscan2
- CNKSR1 | c.1389T>G p.D463E (on ENST00000374253 / NM_001297647.2; = p.D456E on NM_006314.3) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs369423789; called by muse, mutect2, varscan2
- COL4A5 | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 46/471 reads (10%) | catalogued as COSV60361322; called by muse, mutect2
- COL4A5 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60361329; called by muse, mutect2
- CRNKL1 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV55628870; called by muse, mutect2, varscan2
- CSF2RA | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 43/197 reads (22%) | catalogued as rs1316466248, COSV62624552; called by muse, mutect2, varscan2
- CSMD1 | c.8967G>A p.M2989I (on ENST00000520002; = p.M2988I on NM_033225.6) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs749027559, COSV59322288; called by muse, mutect2, varscan2
- CSMD2 | c.1979G>T p.S660I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53911030; called by muse, mutect2, varscan2
- CSTF2 | c.193C>G p.Q65E | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV63376254; called by muse, mutect2, varscan2
- CTNNA3 | c.1978G>T p.A660S | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as COSV65524420; called by muse, mutect2, varscan2
- CTNS | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV50440485; called by muse, mutect2
- CYFIP2 | c.3034G>C p.E1012Q (on ENST00000616178 / NM_001291722.2; = p.E987Q on NM_014376.4) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV59036927; called by muse, mutect2
- DBF4B | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100154589, COSV59260560; called by muse, mutect2, varscan2
- DCPS | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs140993180; called by muse, mutect2, varscan2
- DNAH11 | c.1186A>C p.I396L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV60955234; called by muse, mutect2, varscan2
- DOCK3 | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56520925, COSV56521954; called by muse, mutect2
- DPP4 | c.360C>A p.Y120* | Nonsense Mutation (SNP) | VAF 51/177 reads (29%) | catalogued as COSV62106666; called by muse, mutect2, varscan2
- DYTN | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 89/393 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.417); catalogued as COSV71752029; called by muse, mutect2, varscan2
- EDNRB | c.1243G>A p.V415I (on ENST00000377211 / NM_001201397.1; = p.V325I on NM_000115.5) | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs201437745, COSV57519503; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEF1A1 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100303272, COSV104396981, COSV58549624; called by muse, mutect2, varscan2
- EFNB1 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV52661659; called by muse, mutect2, varscan2
- EFNB2 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 43/149 reads (29%) | catalogued as COSV55364714; called by muse, mutect2, varscan2
- EIF2AK4 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs767768823, COSV55468240; called by muse, mutect2
- EPRS1 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 84/394 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV65098819; called by muse, mutect2, varscan2
- EPRS1 | c.1914C>G p.D638E | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); catalogued as COSV65098825; called by muse, mutect2, varscan2
- EPRS1 | c.631C>A p.H211N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV65098832; called by muse, mutect2, varscan2
- EPS8L2 | c.1837C>A p.R613S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV100585543; called by muse, mutect2, varscan2
- ERICH3 | c.2025A>T p.K675N | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58606411; called by muse, mutect2, varscan2
- ETV3 | c.285-1G>T p.X95_splice | Splice Site (SNP) | VAF 24/108 reads (22%) | catalogued as COSV58748027; called by muse, mutect2, varscan2
- FAT1 | c.6373G>T p.E2125* | Nonsense Mutation (SNP) | VAF 91/268 reads (34%) | catalogued as COSV71673518; called by muse, mutect2, varscan2
- FBXW12 | c.391T>C p.W131R | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56483775; called by muse, mutect2, varscan2
- FBXW7 | c.1963G>T p.E655* (on ENST00000281708 / NM_001349798.2; = p.E575* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 93/259 reads (36%) | catalogued as COSV55900957; called by muse, mutect2, varscan2
- FER1L6 | c.2166G>T p.W722C | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV67549799; called by muse, mutect2, varscan2
- FER1L6 | c.2678A>C p.E893A | Missense Mutation (SNP) | VAF 124/490 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as COSV67549801; called by muse, mutect2, varscan2
- FEZ1 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54028539; called by muse, mutect2, varscan2
- FIGN | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV60766502; called by muse, mutect2, varscan2
- FSHR | c.419A>T p.K140M | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV58623293; called by muse, mutect2, varscan2
- GAB4 | c.1649A>G p.Q550R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs754860854, COSV68753815; called by muse, mutect2, varscan2
- GABRG1 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54953887; called by muse, mutect2, varscan2
- GAR1 | c.623G>T p.R208I | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV56993320; called by muse, varscan2
- GDAP1L1 | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV61157128; called by muse, mutect2, varscan2
- GDPD2 | c.1198C>G p.R400G | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV65531859; called by muse, mutect2
- GLA | c.910A>T p.S304C | Missense Mutation (SNP) | VAF 38/403 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54509103; called by muse, mutect2
- GOT2 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV55331573; called by muse, mutect2, varscan2
- GRM5 | c.799C>G p.H267D | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV59604507, COSV59631601; called by muse, mutect2, varscan2
- GRM8 | c.746A>T p.Q249L | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV100281313, COSV58825043; called by muse, mutect2, varscan2
- GUCY2F | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 46/403 reads (11%) | catalogued as COSV54301725; called by muse, mutect2, varscan2
- HCAR1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.09); catalogued as COSV63674351; called by muse, mutect2, varscan2
- HDC | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as COSV51070172, COSV99984316; called by muse, mutect2, varscan2
- HERC2 | c.13948C>T p.R4650W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762466850, COSV55322614; called by muse, mutect2, varscan2
- HERC6 | c.2632G>C p.G878R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52030000; called by muse, mutect2, varscan2
- HNRNPF | c.919A>T p.N307Y | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV61560984; called by muse, mutect2, varscan2
- HNRNPF | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61560992; called by muse, mutect2, varscan2
- HNRNPU | c.1927C>T p.P643S (on ENST00000283179; = p.P705S on NM_004501.3) | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.565); catalogued as rs746093508, COSV51691071; called by muse, mutect2, varscan2
- HNRNPUL1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV54562220; called by muse, mutect2, varscan2
- ITIH5 | c.1816C>A p.Q606K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.192); catalogued as COSV53663951; called by muse, mutect2, varscan2
- ITM2A | c.268T>A p.C90S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV64810967; called by muse, mutect2, varscan2
- JUP | c.2225A>G p.H742R | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV100159521, COSV60277976; called by muse, mutect2, varscan2
- KATNIP | c.1810T>G p.L604V | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55180234; called by muse, mutect2, varscan2
- KCNJ2 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM035531, CM053931, COSV54661694, COSV54664370; called by muse, varscan2
- KCNJ3 | c.1490C>A p.S497Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV54534535, COSV54536017; called by muse, mutect2
- KLHL1 | c.1699C>A p.L567M | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400777488, COSV64772177; called by muse, mutect2, varscan2
- KNDC1 | c.1813G>T p.V605L | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as rs1314233654, COSV58836772; called by muse, mutect2, varscan2
- KRT31 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV52435063; called by muse, mutect2, varscan2
- LARGE1 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61661650; called by muse, mutect2, varscan2
- LARP4B | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.159); catalogued as rs1336227133, COSV60221416; called by muse, mutect2, varscan2
- LRRC15 | c.1703G>T p.S568I | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV61650073; called by muse, mutect2
- LRRC27 | c.1461A>C p.L487F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV63997050; called by muse, mutect2
- MACF1 | c.8830C>G p.Q2944E | Missense Mutation (SNP) | VAF 8/160 reads (5%) | catalogued as COSV57111556; called by muse, mutect2
- MAP2 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 99/515 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV52290510; called by muse, mutect2, varscan2
- MAP4K3 | c.2385A>G p.I795M | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV55712971; called by muse, mutect2, varscan2
- MAPKBP1 | c.1922+1G>T p.X641_splice (on ENST00000456763 / NM_001128608.2; = p.X635_splice on NM_014994.3) | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52961325; called by muse, mutect2, varscan2
- MAPT | c.2272G>A p.G758R (on ENST00000262410 / NM_001377265.1; = p.G366R on NM_005910.5) | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs948573449, CM121237, COSV52240278; called by muse, mutect2, varscan2
- MDM1 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as COSV57445924; called by muse, mutect2, varscan2
- MDN1 | c.14036G>C p.G4679A | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65521424; called by muse, mutect2
- MIGA1 | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV66223609; called by muse, mutect2
- MPDZ | c.5881G>T p.A1961S (on ENST00000319217 / NM_001330637.2; = p.A1932S on NM_003829.5) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV59917796; called by muse, mutect2, varscan2
- MPHOSPH8 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); catalogued as COSV64055513; called by muse, mutect2
- MRGPRX1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 108/655 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV57107251; called by muse, mutect2, varscan2
- MUC16 | c.25309C>A p.L8437I | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.549); catalogued as COSV67460274, COSV67464951; called by muse, mutect2, varscan2
- MUC16 | c.7432A>G p.M2478V | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV67464961; called by muse, mutect2, varscan2
- MYH6 | c.5284A>C p.T1762P | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62450294; called by muse, mutect2, varscan2
- MYH9 | c.3758A>C p.Q1253P | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53385998; called by muse, mutect2
- MYO10 | c.3623G>T p.R1208L | Missense Mutation (SNP) | VAF 170/326 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs939141866, COSV57016606, COSV57021340; called by muse, varscan2
- MYO10 | c.3622C>T p.R1208C | Missense Mutation (SNP) | VAF 172/327 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762663185, COSV57021366; called by muse, varscan2
- MYO1H | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.95); catalogued as rs1566044250, COSV60445611; called by muse, mutect2, varscan2
- NAP1L3 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.283); catalogued as COSV100220523, COSV59075231; called by muse, mutect2, varscan2
- NCOA2 | c.3244C>T p.Q1082* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV51219318; called by muse, mutect2, varscan2
- NCSTN | c.435T>C p.F145= | Splice Region (SNP) | VAF 50/152 reads (33%) | catalogued as COSV54187559; called by muse, mutect2, varscan2
- NDUFA9 | c.731A>T p.D244V | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56929204, COSV56931173; called by muse, mutect2, varscan2
- NELFA | c.1540G>A p.D514N (on ENST00000542778; = p.D503N on NM_005663.5) | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1426626443, COSV56390532; called by muse, mutect2, varscan2
- NKRF | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 22/172 reads (13%) | catalogued as COSV58661575; called by muse, varscan2
- NLRP12 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV60747251; called by muse, mutect2
- NLRP13 | c.2151C>A p.S717R | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV61621631; called by muse, mutect2, varscan2
- NNT | c.1271G>C p.R424T | Missense Mutation (SNP) | VAF 143/257 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52924912; called by muse, mutect2, varscan2
- NOX4 | c.725A>T p.Y242F | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV54452980; called by muse, mutect2, varscan2
- NSMCE1 | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs937153015, COSV63864277; called by muse, mutect2, varscan2
- NXPH1 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV68314553; called by muse, mutect2, varscan2
- OR4P4 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV58921130, COSV58921916; called by muse, mutect2, varscan2
- OR52A5 | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 31/158 reads (20%) | catalogued as COSV56615031, COSV56615221; called by muse, mutect2, varscan2
- OR5A1 | c.199A>C p.S67R | Missense Mutation (SNP) | VAF 37/393 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV57376667; called by muse, mutect2
- PAH | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV61014139, COSV61016359; called by muse, mutect2, varscan2
- PAPLN | c.1783C>G p.P595A (on ENST00000554301; = p.P568A on NM_173462.4) | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV53717797; called by muse, mutect2, varscan2
- PCDHGA10 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.029); catalogued as rs749121255, COSV53945509; called by muse, mutect2
- PDCD11 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 88/405 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV63933944; called by muse, mutect2, varscan2
- PEA15 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1329677839, COSV58783696; called by muse, mutect2
- PHACTR1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.258); catalogued as COSV60666355; called by muse, mutect2, varscan2
- PHOX2A | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53355478; called by muse, mutect2, varscan2
- PI4KA | c.2564C>T p.T855M | Missense Mutation (SNP) | VAF 44/600 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55410734; called by muse, mutect2
- PIK3C2A | c.3477C>G p.I1159M | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.875); catalogued as COSV56402686; called by muse, mutect2
- PNISR | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65079434; called by muse, mutect2, varscan2
- POU2F1 | c.464C>G p.A155G (on ENST00000541643 / NM_001365848.1; = p.A178G on NM_002697.4) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54816916; called by muse, mutect2, varscan2
- PRDM16 | c.3413C>G p.S1138W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54589771, COSV99577754; called by muse, mutect2
- PROM1 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.036); catalogued as rs760172617, COSV71699420; called by muse, mutect2, varscan2
- PSMA8 | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs1217621677, COSV57602414; called by muse, mutect2
- PTH2R | c.1034G>T p.W345L | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.944); catalogued as rs151296979; called by muse, mutect2, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 34/116 reads (29%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- PTPRZ1 | c.4367T>A p.M1456K | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV66436244; called by muse, mutect2, varscan2
- RAB3IL1 | c.868A>C p.K290Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV57117527; called by muse, mutect2, varscan2
- SALL3 | c.1298G>C p.S433T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV73306042; called by muse, mutect2, varscan2
- SCRIB | c.960C>A p.D320E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57586649; called by muse, mutect2, varscan2
- SEC24C | c.885T>A p.N295K | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as COSV59541772; called by muse, mutect2, varscan2
- SELP | c.2114C>A p.S705* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | catalogued as COSV55251853; called by muse, mutect2, varscan2
- SEPTIN12 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51617026; called by muse, mutect2, varscan2
- SEPTIN12 | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 21/75 reads (28%) | catalogued as COSV51617038; called by muse, mutect2, varscan2
- SERPINB13 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 41/176 reads (23%) | catalogued as COSV54028533; called by muse, mutect2, varscan2
- SIM1 | c.892C>G p.L298V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53491994; called by muse, mutect2
- SLC16A6 | c.1055A>T p.N352I | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59177326; called by muse, mutect2, varscan2
- SLC2A13 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs1269189401, COSV55117325; called by muse, mutect2, varscan2
- SLC8B1 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 26/559 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314816341, COSV52527786; called by muse, mutect2
- SMYD3 | c.820G>A p.D274N (on ENST00000490107 / NM_001375962.1; = p.D215N on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.149); catalogued as COSV63626872; called by muse, mutect2
- SPAM1 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56143537, COSV56147120; called by muse, mutect2, varscan2
- SRSF6 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV54827425; called by muse, mutect2
- ST8SIA2 | c.168A>T p.E56D | Missense Mutation (SNP) | VAF 39/268 reads (15%) | PolyPhen benign (0.3); catalogued as COSV51569350; called by muse, mutect2, varscan2
- TAF1L | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs757557186, COSV54258123; called by muse, mutect2
- TAF1L | c.3433C>T p.R1145W | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs767903653, COSV54261702; called by muse, mutect2, varscan2
- TBC1D14 | c.618C>A p.S206R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV68985765; called by muse, mutect2, varscan2
- TENT4A | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 25/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50095560; called by muse, mutect2
- TIGD6 | c.1343C>A p.A448E | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.145); catalogued as COSV57060958; called by muse, varscan2
- TMEM181 | c.1219G>T p.V407L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV65563137; called by muse, mutect2, varscan2
- TMEM186 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs926224066, COSV51631734, COSV51632856; called by muse, mutect2, varscan2
- TP53 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, varscan2
- TSPAN17 | c.946G>T p.V316F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV53780207; called by muse, mutect2, varscan2
- TTC27 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV58651563; called by muse, mutect2, varscan2
- TTN | c.96589G>C p.E32197Q (on ENST00000591111; = p.E24773Q on NM_003319.4) | Missense Mutation (SNP) | VAF 34/267 reads (13%) | PolyPhen probably damaging (0.998); catalogued as COSV60049660; called by muse, mutect2, varscan2
- TTN | c.85637T>C p.I28546T (on ENST00000591111; = p.I21122T on NM_003319.4) | Missense Mutation (SNP) | VAF 33/132 reads (25%) | PolyPhen benign (0.005); catalogued as COSV60049736; called by muse, mutect2, varscan2
- ULK1 | c.1783G>C p.G595R | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV58855338, COSV58856653; called by muse, mutect2, varscan2
- UPF3B | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.45); catalogued as COSV52229992, COSV52231789; called by muse, mutect2
- USP49 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV51896950, COSV99790207; called by muse, mutect2
- WNT9B | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 48/497 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV51518405; called by muse, mutect2
- WWP2 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63124901; called by muse, mutect2, varscan2
- ZBBX | c.2213A>T p.Q738L | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56789028; called by muse, mutect2, varscan2
- ZNF236 | c.2918A>G p.N973S | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV53488053; called by muse, mutect2, varscan2
- ZNF518B | c.2289G>T p.K763N | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.123); catalogued as COSV58721718, COSV58722557; called by muse, mutect2, varscan2
- ZNF527 | c.50G>T p.R17I | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV62230494; called by muse, mutect2, varscan2
- ZNF91 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 34/271 reads (13%) | catalogued as COSV56080497, COSV56084325; called by muse, mutect2, varscan2
- CHRDL1 | c.1223-2A>G p.X408_splice (on ENST00000372045; = p.X414_splice on NM_145234.4) | Splice Site (SNP) | VAF 5/123 reads (4%) | called by muse, mutect2
- CTDSP2 | c.719dup p.M240Ifs*5 | Frame Shift Ins (INS) | VAF 14/99 reads (14%) | called by mutect2, pindel, varscan2
- FAT1 | c.3206_3214delinsG p.I1069Sfs*3 | Frame Shift Del (DEL) | VAF 25/238 reads (11%) | called by pindel, varscan2*
- GDF3 | c.124del p.Q42Rfs*10 | Frame Shift Del (DEL) | VAF 31/119 reads (26%) | called by mutect2, pindel, varscan2
- HLA-E | c.790_799del p.K264Lfs*27 | Frame Shift Del (DEL) | VAF 16/139 reads (12%) | called by mutect2, pindel
- IGKV3D-11 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBTD1 | c.1676_1682del p.P559Hfs*30 | Frame Shift Del (DEL) | VAF 23/226 reads (10%) | called by mutect2, pindel, varscan2
- MTMR1 | c.1330del p.R444Efs*11 | Frame Shift Del (DEL) | VAF 22/222 reads (10%) | called by mutect2, pindel, varscan2
- NBPF15 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 77/423 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PCDHAC2 | c.1850del p.N617Mfs*8 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, varscan2
- POM121C | c.2653C>A p.P885T (on ENST00000607367; = p.P643T on NM_001099415.3) | Missense Mutation (SNP) | VAF 53/365 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- PRAMEF18 | c.864C>A p.I288= | Splice Region (SNP) | VAF 60/445 reads (13%) | called by muse, varscan2
- RBP3 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- SALL4 | c.1412_1415del p.S471* | Frame Shift Del (DEL) | VAF 30/272 reads (11%) | called by pindel, varscan2
- TDRD6 | c.1588_1599del p.L530_V533del | In Frame Del (DEL) | VAF 34/294 reads (12%) | called by mutect2, pindel
- ABCC10 | c.2247C>T p.L749= (on ENST00000372530 / NM_001198934.2; = p.L721= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as rs763453216, COSV55087618; called by muse, mutect2
- ADGRB2 | c.4374C>A p.S1458= | Silent (SNP) | VAF 32/156 reads (21%) | catalogued as COSV57073562, COSV57078222; called by muse, mutect2, varscan2
- AFF2 | c.1674G>C p.L558= | Silent (SNP) | VAF 85/707 reads (12%) | catalogued as COSV53984000; called by muse, mutect2, varscan2
- ANKRD30A | c.543G>C p.T181= (on ENST00000611781; = p.T125= on NM_052997.2) | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as COSV64609214, COSV64609913; called by muse, mutect2, varscan2
- BASP1 | c.462C>T p.P154= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs918326143, COSV59470958; called by muse, mutect2, varscan2
- BAZ1B | c.2305A>C p.R769= | Silent (SNP) | VAF 18/223 reads (8%) | catalogued as COSV59991026; called by muse, mutect2
- CCDC50 | c.696G>A p.R232= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV101165289; called by muse, mutect2, varscan2
- CDC27 | c.903C>T p.Y301= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV50383669, COSV50643098; called by muse, mutect2, varscan2
- CELSR2 | c.8373A>T p.P2791= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV54771529; called by muse, mutect2, varscan2
- CEP164 | c.2778T>C p.D926= | Silent (SNP) | VAF 66/423 reads (16%) | catalogued as COSV54041096; called by muse, mutect2, varscan2
- CST11 | c.153C>A p.I51= | Silent (SNP) | VAF 52/391 reads (13%) | catalogued as COSV63140115; called by muse, mutect2, varscan2
- CYP7A1 | c.384T>A p.T128= | Silent (SNP) | VAF 48/219 reads (22%) | catalogued as COSV56963472; called by muse, mutect2, varscan2
- DOCK6 | c.594A>C p.A198= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV53914679; called by muse, mutect2, varscan2
- EFNB1 | c.216C>T p.P72= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52661669; called by muse, mutect2, varscan2
- EPHB3 | c.1227G>T p.R409= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as COSV57805857; called by muse, mutect2, varscan2
- FBXO27 | c.813G>A p.V271= | Silent (SNP) | VAF 13/155 reads (8%) | catalogued as COSV53072370; called by muse, mutect2
- FLG | c.10188T>A p.S3396= | Silent (SNP) | VAF 137/797 reads (17%) | catalogued as COSV64241676, COSV64247628; called by muse, mutect2, varscan2
- GRIA3 | c.2094G>T p.V698= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as COSV52059045; called by muse, mutect2, varscan2
- IGHV1-46 | c.216T>A p.P72= | Silent (SNP) | VAF 10/295 reads (3%) | catalogued as rs540499178; called by muse, mutect2
- IGHV1OR15-9 | c.33G>C p.V11= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as rs759530603; called by muse, mutect2, varscan2
- KCNK9 | c.726C>T p.V242= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs113907649; called by muse, mutect2, varscan2
- KIAA1210 | c.4566C>A p.S1522= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV68177137, COSV68179007; called by muse, mutect2, varscan2
- KIAA1549L | c.5154C>A p.A1718= (on ENST00000321505; = p.A2015= on NM_012194.3) | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV58588356; called by muse, mutect2, varscan2
- KIF18B | c.360G>T p.L120= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV100192190; called by muse, mutect2, varscan2
- KY | c.1773C>G p.A591= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV71017253; called by muse, mutect2
- LGI1 | c.135G>A p.V45= | Silent (SNP) | VAF 20/224 reads (9%) | catalogued as COSV65057983; called by muse, mutect2
- MAP3K21 | c.912A>T p.T304= | Silent (SNP) | VAF 59/166 reads (36%) | catalogued as COSV64043163, COSV64044602; called by muse, mutect2, varscan2
- MFSD5 | c.267C>A p.V89= | Silent (SNP) | VAF 74/669 reads (11%) | catalogued as COSV61565524; called by muse, mutect2, varscan2
- MYO6 | c.576T>C p.F192= | Silent (SNP) | VAF 44/213 reads (21%) | catalogued as COSV64118929; called by muse, mutect2, varscan2
- MYPN | c.2664G>A p.G888= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as rs1351171087, COSV62731580, COSV62733840; called by muse, varscan2
- NKRF | c.627G>T p.A209= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs1387498180, COSV58661560; called by muse, varscan2
- NOS1 | c.1506C>A p.A502= | Silent (SNP) | VAF 39/182 reads (21%) | catalogued as COSV57612107; called by muse, varscan2
- NRXN1 | c.2937A>G p.S979= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV58451577; called by muse, mutect2
- OR4C46 | c.597C>G p.A199= | Silent (SNP) | VAF 43/240 reads (18%) | catalogued as COSV60219302; called by muse, mutect2, varscan2
- OR6C1 | c.792T>C p.D264= | Silent (SNP) | VAF 38/231 reads (16%) | catalogued as rs748579568, COSV65573371; called by muse, mutect2, varscan2
- OTOGL | c.2268G>A p.S756= (on ENST00000547103; = p.S747= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs1036677659, COSV101509275; called by muse, mutect2, varscan2
- PBRM1 | c.1782C>T p.F594= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV56275776; called by muse, mutect2, varscan2
- PCDHGA10 | c.2250T>G p.V750= | Silent (SNP) | VAF 44/161 reads (27%) | catalogued as rs777503392, COSV53945497; called by muse, mutect2
- PGK2 | c.132C>T p.I44= | Silent (SNP) | VAF 67/238 reads (28%) | catalogued as COSV59163816; called by muse, mutect2, varscan2
- PJA1 | c.1677A>G p.A559= (on ENST00000361478 / NM_145119.4; = p.A371= on NM_022368.5) | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as COSV64053131; called by muse, mutect2, varscan2
- PLEKHA6 | c.783G>T p.G261= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as rs751835630, COSV55333582; called by muse, mutect2, varscan2
- PLXNB2 | c.5394G>A p.T1798= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs563052435, COSV63780802; called by muse, mutect2, varscan2
- POLA1 | c.1803C>G p.V601= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as COSV66886145; called by muse, mutect2, varscan2
- POLR1F | c.801G>C p.A267= | Silent (SNP) | VAF 255/1392 reads (18%) | catalogued as COSV55997996, COSV55998463; called by muse, mutect2, varscan2
- PRR23B | c.222C>T p.D74= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV61493268, COSV61493598; called by muse, mutect2
- RFX7 | c.3501A>G p.A1167= (on ENST00000559447 / NM_001368074.1; = p.A1264= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV57963265; called by muse, mutect2, varscan2
- SLC17A6 | c.324C>G p.G108= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV54136298; called by muse, mutect2, varscan2
- SLC6A19 | c.690C>G p.P230= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV58671177; called by muse, mutect2
- SLIT1 | c.4140C>A p.P1380= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99821405; called by muse, mutect2, varscan2
- SYT13 | c.906C>T p.N302= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as rs779255449, COSV50073607; called by muse, mutect2, varscan2
- TH | c.1515C>A p.A505= (on ENST00000381178 / NM_199292.3; = p.A474= on NM_000360.4) | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV51747087; called by muse, mutect2, varscan2
- TNRC18 | c.8169G>A p.A2723= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1359811661, COSV60307203; called by muse, mutect2, varscan2
- TSC22D2 | c.1557T>A p.P519= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV62622580; called by muse, mutect2
- TTN | c.91282T>C p.L30428= (on ENST00000591111; = p.L23004= on NM_003319.4) | Silent (SNP) | VAF 67/258 reads (26%) | catalogued as rs770663539, COSV60049689; called by muse, mutect2, varscan2
- TUBA3C | c.27G>T p.V9= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as COSV67139274; called by muse, mutect2, varscan2
- VMA21 | c.294C>A p.G98= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV57756569; called by muse, mutect2
- WBP4 | c.276A>G p.P92= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as COSV65273916; called by muse, mutect2
- ZFC3H1 | c.15T>C p.D5= | Silent (SNP) | VAF 12/288 reads (4%) | catalogued as COSV57348564; called by muse, mutect2
- ZFHX4 | c.9348C>A p.S3116= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV50780425; called by muse, mutect2
- ZNF573 | c.1902T>C p.G634= (on ENST00000536220 / NM_001172692.1; = p.G576= on NM_152360.3) | Silent (SNP) | VAF 15/340 reads (4%) | catalogued as COSV59825213; called by muse, mutect2
- ZNF667 | c.1266G>A p.K422= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs1568831225, COSV52634392; called by muse, mutect2, varscan2
- AGAP7P | n.1208C>A | RNA (SNP) | VAF 55/264 reads (21%) | called by muse, mutect2, varscan2
- ANKRD33 | c.664+38G>A | Intron (SNP) | VAF 8/62 reads (13%) | catalogued as rs371567187, COSV100001051; called by muse, mutect2, varscan2
- DPP6 | c.627+21114G>T | Intron (SNP) | VAF 27/169 reads (16%) | catalogued as COSV100125684; called by muse, mutect2, varscan2
- DST | c.4297-3919C>T | Intron (SNP) | VAF 77/195 reads (39%) | catalogued as COSV99755773, COSV99756095; called by muse, mutect2, varscan2
- HTN1 | c.-2C>A | 5'UTR (SNP) | VAF 4/80 reads (5%) | catalogued as COSV99887521; called by muse, mutect2
- PANK2 | c.1536+455G>C | Intron (SNP) | VAF 9/188 reads (5%) | catalogued as COSV57254249; called by muse, mutect2
- PDE4B | c.281+74194A>C | Intron (SNP) | VAF 30/150 reads (20%) | catalogued as rs116785815, COSV100303632; called by muse, mutect2, varscan2
- PKD1L2 | n.723G>A | RNA (SNP) | VAF 15/58 reads (26%) | catalogued as rs962181647; called by muse, mutect2, varscan2
- SLIT3 | c.198-12197C>T | Intron (SNP) | VAF 21/75 reads (28%) | catalogued as rs528719712, COSV60607601; called by muse, mutect2, varscan2
- SNORD116-2 | n.89G>C | RNA (SNP) | VAF 61/210 reads (29%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1598C>T | Intron (SNP) | VAF 75/247 reads (30%) | catalogued as COSV100314277; called by muse, mutect2, varscan2
- TMEM99 | n.842C>G | RNA (SNP) | VAF 38/386 reads (10%) | catalogued as rs774061894, COSV56982950; called by muse, mutect2
- TTN | c.10361-3802C>G | Intron (SNP) | VAF 49/232 reads (21%) | catalogued as COSV60049780; called by muse, mutect2, varscan2
- UBE2D3 | c.398+478G>T | Intron (SNP) | VAF 45/169 reads (27%) | catalogued as COSV100414924; called by muse, mutect2, varscan2
- WNK1 | c.2140-2994G>T | Intron (SNP) | VAF 20/37 reads (54%) | catalogued as COSV60032855; called by muse, mutect2, varscan2
